Gene-level copy-number profile of tumor specimen TCGA-3H-AB3T-01A from TCGA case TCGA-3H-AB3T, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 79.2 years (28,925 days).
Specimen TCGA-3H-AB3T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.f6adb8e5-5005-42f8-92e9-3a243e992e28.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3H-AB3T-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8b5162ac-27bf-4e96-9199-24532970f687

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 15,908; copy number 2: 43,207; copy number 3: 696.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3H-AB3T-01A-11D-A39Q-01): tumor purity 0.44, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 13,495. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
